Somatic mutation profile of tumor specimen 0DGIK1 from CCDI case PBBTCE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 7.7 years (2,812 days).
Specimen 0DGIK1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80835816-a912-420e-96de-ae869cd16948.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGIK2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/651e1091-61aa-4841-a234-443839646889

The open-access MAF lists 53 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Intron 5, Nonsense Mutation 5, 3'UTR 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIFM2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs376374471; called by muse, mutect2, varscan2
- ALK | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs765309299; called by muse, mutect2, varscan2
- CFAP47 | c.8386G>C p.D2796H | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as rs1402059653, COSV66215765; called by muse, mutect2, varscan2
- CLIP1 | c.2458A>T p.S820C (on ENST00000620786 / NM_001247997.1; = p.S809C on NM_002956.2) | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs776946641; called by muse, varscan2
- MAPK4 | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1023559689, COSV68541263; called by muse, mutect2, varscan2
- POTEF | c.2778G>C p.E926D | Missense Mutation (SNP) | VAF 33/239 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as COSV62540332; called by muse, mutect2, varscan2
- TG | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99601766; called by muse, mutect2, varscan2
- TRIM24 | c.1456C>T p.R486W | Missense Mutation (SNP) | VAF 42/419 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs778431830, COSV100631102; called by muse, mutect2
- TRPM1 | c.4369G>T p.E1457* | Nonsense Mutation (SNP) | VAF 51/343 reads (15%) | catalogued as COSV56636913; called by muse, mutect2, varscan2
- ABCA12 | c.650T>A p.L217H | Missense Mutation (SNP) | VAF 67/492 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.371); called by mutect2, varscan2
- ABCB8 | c.286C>A p.L96I (on ENST00000297504 / NM_001282291.2; = p.L79I on NM_007188.5) | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ALS2CL | c.2042C>T p.S681L | Missense Mutation (SNP) | VAF 25/302 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2
- ANKS1A | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 50/284 reads (18%) | called by mutect2, varscan2
- CCDC102B | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 53/417 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CDADC1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 110/811 reads (14%) | called by muse, mutect2, varscan2
- CNGB3 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 74/976 reads (8%) | called by muse, mutect2
- CXXC1 | c.1839C>G p.D613E | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CYLD | c.2643C>A p.D881E | Missense Mutation (SNP) | VAF 60/392 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- DGKI | c.2052T>A p.C684* | Nonsense Mutation (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- ERAP1 | c.702C>A p.D234E | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- HRG | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 39/375 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- MYOCD | c.2044G>C p.V682L | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.1813C>A p.P605T | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.017); called by muse, mutect2
- NOC4L | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2
- SERPING1 | c.808A>C p.T270P | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLITRK1 | c.1803G>T p.E601D | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- SRSF3 | c.207-1_207del p.X69_splice | Splice Site (DEL) | VAF 62/376 reads (16%) | called by mutect2, varscan2
- TBXAS1 | c.805C>A p.Q269K | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- TPX2 | c.1781G>T p.C594F | Missense Mutation (SNP) | VAF 74/448 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- YBX3 | c.322_326+17del p.X108_splice | Splice Site (DEL) | VAF 106/402 reads (26%) | called by mutect2, varscan2
- ZBBX | c.1780C>A p.L594I | Missense Mutation (SNP) | VAF 64/545 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); called by mutect2, varscan2
- ZNF254 | c.124A>G p.M42V | Missense Mutation (SNP) | VAF 55/512 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- ZNF428 | c.194A>G p.Y65C | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ADGRG7 | c.2391C>A p.I797= | Silent (SNP) | VAF 48/335 reads (14%) | called by muse, mutect2, varscan2
- ARID1A | c.5505G>A p.Q1835= | Silent (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
- ASB15 | c.645C>A p.G215= | Silent (SNP) | VAF 49/450 reads (11%) | catalogued as rs758785121; called by muse, varscan2
- C4BPA | c.1005C>A p.G335= | Silent (SNP) | VAF 49/460 reads (11%) | called by mutect2, varscan2
- C4orf54 | c.1887G>T p.R629= | Silent (SNP) | VAF 42/273 reads (15%) | catalogued as rs1413973483; called by muse, mutect2, varscan2
- DUS4L | c.721A>C p.R241= | Silent (SNP) | VAF 128/764 reads (17%) | catalogued as rs369335142; called by muse, mutect2, varscan2
- GDF11 | c.900G>A p.L300= | Silent (SNP) | VAF 48/289 reads (17%) | called by muse, mutect2, varscan2
- HCLS1 | c.351C>A p.A117= | Silent (SNP) | VAF 43/431 reads (10%) | called by muse, mutect2, varscan2
- IRS2 | c.645G>A p.G215= | Silent (SNP) | VAF 42/396 reads (11%) | called by muse, mutect2
- OR5R1 | c.765G>T p.L255= | Silent (SNP) | VAF 73/528 reads (14%) | catalogued as COSV56571635; called by muse, mutect2, varscan2
- RHPN2 | c.1389G>T p.L463= | Silent (SNP) | VAF 29/271 reads (11%) | called by muse, mutect2, varscan2
- TENM1 | c.5142T>C p.T1714= | Silent (SNP) | VAF 75/254 reads (30%) | called by muse, mutect2, varscan2
- UQCRFS1 | c.219T>C p.P73= | Silent (SNP) | VAF 63/553 reads (11%) | called by muse, varscan2
- BTK | c.1566+36C>A | Intron (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- C9orf78 | c.144-84C>T | Intron (SNP) | VAF 5/31 reads (16%) | catalogued as rs896991869; called by muse, mutect2, varscan2
- HIKESHI | c.540-35C>A | Intron (SNP) | VAF 65/241 reads (27%) | catalogued as COSV99563665; called by muse, mutect2, varscan2
- NFASC | c.1831+109C>T | Intron (SNP) | VAF 13/95 reads (14%) | catalogued as rs1474123097; called by muse, mutect2, varscan2
- PRRC2A | c.*49A>G | 3'UTR (SNP) | VAF 16/99 reads (16%) | catalogued as COSV99277002; called by muse, mutect2, varscan2
- RXFP1 | c.187+87C>A | Intron (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- ZNF740 | c.*5497G>A | 3'UTR (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
